Gene-level copy-number profile of tumor specimen TCGA-UW-A72Q-01A from TCGA case TCGA-UW-A72Q, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 56.7 years (20,700 days).
Specimen TCGA-UW-A72Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d803e4b1-0b67-4d38-b4f9-49ce396dd8b6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-UW-A72Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/0ce15963-f4ae-4944-bb39-7e15aac01138

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 26,277; copy number 2: 32,459; copy number 3: 100.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr6:170,615,515–170,738,536, 1 gene (within-gene range 0–1): AL672310.1.
- chr6:170,695,313–170,737,777, 2 genes: AL731661.1, AL731684.1.
- chr8:7,200,756–7,200,857, 1 gene: AF228730.1.
- chr8:7,715,443–8,226,614, 38 genes: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:12,087,396–12,196,280, 12 genes: RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1.
- chr21:43,092,956–43,107,570, 1 gene: U2AF1.
- chr21:43,115,334–43,141,092, 2 genes: MRPL51P2, FRGCA.
- chr22:18,361,820–18,653,617, 18 genes: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,733,914–18,843,399, 4 genes (within-gene range 0–1): FAM230E, GGT3P, AC008132.2, E2F6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 23,421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
